Somatic mutation profile of tumor specimen TCGA-CV-7104-01A (aliquot TCGA-CV-7104-01A-11D-2012-08) from TCGA case TCGA-CV-7104, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 61.2 years (22,349 days).
Specimen TCGA-CV-7104-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a48d15f-f9af-4d52-adb3-2c4312df5efe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7104-10A (Blood Derived Normal), aliquot TCGA-CV-7104-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26f26c5e-b977-4257-a83c-86c869e204bd

The open-access MAF lists 113 somatic variants for this specimen: 85 protein-altering or splice-affecting, 24 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 24, Nonsense Mutation 8, Frame Shift Del 3, In Frame Del 3, Splice Site 3, Intron 3, Frame Shift Ins 2, Splice Region 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GFM1 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 28/83 reads (34%) | catalogued as rs119470019, CM070936; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.673-1G>A p.X225_splice | Splice Site (SNP) | VAF 17/71 reads (24%) | hotspot (GDC flag); catalogued as rs878854073, CS011061, COSV52662773, COSV52705331, COSV52707963, COSV53154363; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADCY2 | c.71A>T p.D24V | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100603373; called by muse, mutect2, varscan2
- AK5 | c.1258G>T p.E420* (on ENST00000354567 / NM_174858.3; = p.E394* on NM_012093.4) | Nonsense Mutation (SNP) | VAF 19/72 reads (26%) | catalogued as COSV100643129; called by muse, mutect2, varscan2
- ALG2 | c.577C>G p.H193D | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV53060748; called by muse, mutect2, varscan2
- AMBP | c.87C>G p.I29M | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV99469206; called by muse, mutect2, varscan2
- APBA1 | c.2389G>A p.V797M | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777421578, COSV99596570; called by muse, mutect2, varscan2
- ARHGEF5 | c.4635C>A p.D1545E | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99282997; called by muse, mutect2, varscan2
- ARMC1 | c.70C>G p.L24V | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV99395078; called by muse, mutect2, varscan2
- ART1 | c.671G>T p.C224F | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99167207; called by muse, mutect2, varscan2
- BAZ1B | c.2647G>T p.A883S | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.223); catalogued as COSV100289915; called by muse, mutect2, varscan2
- BCOR | c.2179C>A p.P727T | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100653573; called by muse, mutect2, varscan2
- BLZF1 | c.146G>C p.S49T | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.05); catalogued as COSV100250709; called by muse, mutect2, varscan2
- BPTF | c.5786G>T p.G1929V | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV100075388; called by muse, mutect2, varscan2
- CAP1 | c.30A>T p.R10S | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100472513; called by muse, mutect2, varscan2
- CDH12 | c.2116C>A p.P706T | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); catalogued as COSV101202475; called by muse, mutect2, varscan2
- CEMIP2 | c.1445G>A p.R482K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as COSV100987434; called by muse, mutect2, varscan2
- CSDE1 | c.1745C>T p.T582I (on ENST00000358528 / NM_001007553.3; = p.T551I on NM_007158.6) | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV99795430; called by muse, mutect2, varscan2
- DGKK | c.3229C>T p.Q1077* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV101053111; called by muse, mutect2, varscan2
- DNAH8 | c.7201G>A p.D2401N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100546319; called by muse, mutect2, varscan2
- EIF3L | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.524); catalogued as rs759062483, COSV101094605; called by muse, mutect2, varscan2
- ESRP1 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100619435; called by muse, mutect2
- ESRP1 | c.930T>A p.G310= | Splice Region (SNP) | VAF 8/34 reads (24%) | catalogued as rs1204240039, COSV100619438; called by muse, mutect2
- FAM81A | c.682C>A p.Q228K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV99893416; called by muse, mutect2
- FAT2 | c.4583G>A p.R1528Q | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756688058, COSV99943537; called by muse, mutect2, varscan2
- FPGS | c.1241A>G p.N414S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.523); catalogued as rs751038682, COSV61227609; called by muse, mutect2, varscan2
- GGNBP2 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.964); catalogued as rs755657833; called by muse, mutect2, varscan2
- GRIN2D | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 52/194 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV53517693; called by muse, mutect2, varscan2
- HEATR5A | c.3014G>A p.R1005H | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1408136043, COSV101120245; called by muse, mutect2, varscan2
- HKDC1 | c.283G>T p.V95L | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs775603000, COSV100664660; called by muse, mutect2, varscan2
- INPP5J | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs763939360, COSV100459611; called by muse, mutect2, varscan2
- ITPA | c.120T>G p.I40M | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV101200070; called by muse, mutect2, varscan2
- JMJD1C | c.4862C>T p.T1621I | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV100550700; called by muse, mutect2, varscan2
- KIAA1522 | c.2621del p.A874Gfs*172 (on ENST00000373480 / NM_001198972.2; = p.A933Gfs*172 on NM_020888.3) | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | catalogued as COSV53865479; called by mutect2, pindel, varscan2
- LSM2 | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.833); catalogued as rs1401439762, COSV100989567; called by muse, mutect2, varscan2
- MAP2 | c.203C>G p.S68* | Nonsense Mutation (SNP) | VAF 23/78 reads (29%) | catalogued as COSV52307996, COSV99560887; called by muse, mutect2, varscan2
- MBTPS1 | c.3127C>A p.Q1043K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.72); PolyPhen possibly damaging (0.761); catalogued as COSV58569139; called by muse, mutect2, varscan2
- MFSD10 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.233); catalogued as rs780962236, COSV99295872; called by muse, mutect2, varscan2
- MMS19 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as rs533058221, COSV100512973; called by muse, mutect2, varscan2
- MUC16 | c.33167G>T p.S11056I | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as COSV101200492; called by muse, mutect2, varscan2
- MYH4 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as rs773365313, COSV55112414; called by muse, mutect2, varscan2
- NCBP2 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as rs1170003941, COSV100052121; called by muse, mutect2, varscan2
- NIBAN2 | c.1826C>T p.S609L | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1273088198, COSV55939606; called by mutect2, varscan2
- NOS3 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771783555, COSV52491980, COSV52494026; called by mutect2, varscan2
- NR3C1 | c.2002A>C p.T668P | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99196465; called by muse, mutect2, varscan2
- OR1N2 | c.716A>C p.K239T | Missense Mutation (SNP) | VAF 59/190 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101031432; called by muse, mutect2, varscan2
- OR5D13 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV100686871, COSV100686945, COSV62333789; called by muse, mutect2
- PARD3B | c.2710G>C p.E904Q (on ENST00000406610 / NM_001302769.2; = p.E835Q on NM_057177.7) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV100594332; called by muse, mutect2
- PHF21A | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as rs1482378168, COSV57651810; called by muse, mutect2, varscan2
- PIGC | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as rs750507601, COSV99278290; called by muse, mutect2, varscan2
- POMGNT1 | c.1102G>A p.V368M | Missense Mutation (SNP) | VAF 14/37 reads (38%) | PolyPhen probably damaging (0.966); catalogued as rs1332597566, COSV100915573; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POU5F1 | c.881_883del p.Q294del | In Frame Del (DEL) | VAF 6/21 reads (29%) | catalogued as rs765569430; called by mutect2, pindel, varscan2
- RECQL4 | c.3280G>A p.E1094K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV100020716; called by muse, mutect2, varscan2
- RFLNA | c.545C>A p.T182N (on ENST00000546355 / NM_001365156.1; = p.T101N on NM_181709.4) | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100133369; called by muse, mutect2, varscan2
- RLF | c.505A>T p.N169Y | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV101035554; called by muse, mutect2, varscan2
- S100A11 | c.178C>T p.L60F | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.423); catalogued as COSV99643254; called by muse, mutect2, varscan2
- SERPINI2 | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99248114; called by muse, mutect2
- SETD6 | c.917A>G p.N306S (on ENST00000219315 / NM_001160305.4; = p.N282S on NM_024860.3) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV99262331; called by muse, mutect2, varscan2
- SGK1 | c.75C>T p.I25= | Splice Region (SNP) | VAF 37/158 reads (23%) | catalogued as COSV99398642; called by muse, mutect2, varscan2
- SLC32A1 | c.1301C>T p.T434M | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.095); catalogued as COSV54147145; called by muse, mutect2, varscan2
- SLC52A1 | c.596C>A p.A199E | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV99643482; called by muse, mutect2, varscan2
- SMG6 | c.2090A>T p.K697M | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV99558445; called by muse, mutect2, varscan2
- ST6GAL2 | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 55/190 reads (29%) | PolyPhen benign (0.003); catalogued as COSV100868121; called by muse, mutect2, varscan2
- SULF1 | c.2608G>T p.E870* | Nonsense Mutation (SNP) | VAF 48/95 reads (51%) | catalogued as COSV99483637; called by muse, mutect2, varscan2
- TAF1L | c.2287G>A p.E763K | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99645023; called by muse, mutect2
- TNKS2 | c.3185C>T p.A1062V | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100861127; called by muse, mutect2, varscan2
- TNPO2 | c.918G>A p.M306I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV100790384; called by muse, mutect2, varscan2
- TP53 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 56/250 reads (22%) | catalogued as CM107390, COSV52689258; called by muse, mutect2, varscan2
- TRIM69 | c.310A>T p.K104* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | catalogued as COSV100274341; called by muse, mutect2, varscan2
- TRPS1 | c.339C>G p.F113L (on ENST00000220888 / NM_001330599.2; = p.F126L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.075); catalogued as COSV99632395; called by muse, mutect2, varscan2
- USH2A | c.1898C>G p.S633W | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as CM149915, COSV56437947; called by muse, mutect2, varscan2
- WNK1 | c.3950A>G p.E1317G (on ENST00000315939 / NM_018979.4; = p.E1070G on NM_014823.3) | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV100267885; called by muse, mutect2, varscan2
- WSCD2 | c.683-1G>T p.X228_splice | Splice Site (SNP) | VAF 23/121 reads (19%) | catalogued as COSV54584810, COSV99774884; called by muse, mutect2, varscan2
- ZFHX3 | c.10810G>A p.A3604T | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs745550429, COSV51738826; called by muse, mutect2
- ZNF451 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); catalogued as COSV100674982; called by muse, mutect2, varscan2
- ZNF596 | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.49); catalogued as rs766377726, COSV57655691; called by muse, mutect2, varscan2
- ZNF790 | c.1808A>T p.N603I | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV100764859; called by muse, mutect2, varscan2
- EPHA2 | c.275_278dup p.I94Afs*5 | Frame Shift Ins (INS) | VAF 36/80 reads (45%) | called by mutect2, pindel, varscan2
- FOSL2 | c.593_594dup p.R199Afs*22 | Frame Shift Ins (INS) | VAF 26/98 reads (27%) | called by mutect2, pindel, varscan2
- HYAL2 | c.1009_1011+6del p.X337_splice | Splice Site (DEL) | VAF 14/54 reads (26%) | called by mutect2, pindel, varscan2
- KCNJ3 | c.984del p.P329Lfs*2 | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | called by mutect2, pindel, varscan2
- TAS2R7 | c.727_729del p.L243del | In Frame Del (DEL) | VAF 11/63 reads (17%) | called by pindel, varscan2
- TENT4B | c.1701del p.C567* (on ENST00000561678 / NM_001365323.2; = p.C552* on NM_001040284.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- TRGV9 | c.23C>G p.S8* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2
- ZMYM1 | c.1367_1369del p.I456del | In Frame Del (DEL) | VAF 17/46 reads (37%) | called by mutect2, pindel, varscan2
- ADAMTS12 | c.3744G>T p.L1248= | Silent (SNP) | VAF 57/237 reads (24%) | catalogued as COSV100711352, COSV61264620; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.162G>A p.S54= | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as rs1366729601, COSV99783834; called by muse, mutect2, varscan2
- ANKS6 | c.399C>T p.H133= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs758105673, COSV100782351; called by muse, mutect2, varscan2
- B4GALNT1 | c.1077C>T p.F359= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as rs541794502, COSV100247223; ClinVar: likely benign; called by muse, mutect2, varscan2
- CLSTN1 | c.1260C>G p.L420= (on ENST00000377298 / NM_001009566.3; = p.L410= on NM_014944.4) | Silent (SNP) | VAF 35/111 reads (32%) | catalogued as COSV100790686; called by muse, mutect2, varscan2
- DENND4B | c.3705C>T p.D1235= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV100768789; called by muse, mutect2, varscan2
- DNAJC13 | c.204C>T p.F68= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV53460426; called by muse, mutect2, varscan2
- FMN2 | c.4332C>A p.I1444= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as rs764305551, COSV60426950, COSV60434723; called by muse, mutect2, varscan2
- HP | c.921C>T p.D307= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100577572; called by muse, mutect2, varscan2
- MECOM | c.465C>A p.V155= (on ENST00000468789 / NM_001105078.4; = p.V343= on NM_004991.4) | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV52958434, COSV99244974; called by muse, mutect2, varscan2
- OR2C1 | c.237C>G p.P79= | Silent (SNP) | VAF 58/104 reads (56%) | catalogued as COSV100514974; called by muse, varscan2
- PCDHGB6 | c.2016G>A p.L672= | Silent (SNP) | VAF 69/125 reads (55%) | catalogued as COSV99542144; called by muse, mutect2, varscan2
- PCNX3 | c.3732C>T p.F1244= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs781719158, COSV63134850; called by muse, mutect2, varscan2
- POLG | c.2844C>T p.I948= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs1380370898, COSV99174921; called by muse, mutect2, varscan2
- RLF | c.504G>A p.G168= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV101035549; called by muse, mutect2, varscan2
- SERPINI2 | c.558A>G p.K186= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV99248119; called by muse, mutect2
- STAMBPL1 | c.147A>G p.R49= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV100905144; called by muse, mutect2, varscan2
- TADA2A | c.426A>G p.T142= | Silent (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2
- TAS2R38 | c.33C>G p.S11= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as rs1297484934, COSV101516472; called by muse, mutect2, varscan2
- THOP1 | c.1512G>A p.P504= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs780216810, COSV100310670; called by muse, mutect2, varscan2
- TNNT3 | c.636G>A p.K212= (on ENST00000397301 / NM_001367846.1; = p.K201= on NM_006757.4) | Silent (SNP) | VAF 52/215 reads (24%) | catalogued as COSV99548619; called by muse, mutect2, varscan2
- TXNDC16 | c.45C>G p.V15= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV99909404; called by muse, mutect2, varscan2
- UGT3A2 | c.54G>T p.L18= | Silent (SNP) | VAF 102/249 reads (41%) | catalogued as COSV99236626; called by muse, mutect2, varscan2
- WWC1 | c.1317C>G p.P439= | Silent (SNP) | VAF 32/147 reads (22%) | catalogued as COSV99515426; called by muse, mutect2, varscan2
- CARMIL1 | c.614+1382C>T | Intron (SNP) | VAF 10/41 reads (24%) | catalogued as rs774672272; called by muse, mutect2, varscan2
- PKD1L2 | n.2805C>T | RNA (SNP) | VAF 6/15 reads (40%) | catalogued as rs746277114; called by muse, mutect2, varscan2
- TSC22D1 | c.2913-423G>A | Intron (SNP) | VAF 29/191 reads (15%) | catalogued as COSV54926566; called by muse, mutect2, varscan2
- ZNF783 | c.802+3636C>G | Intron (SNP) | VAF 11/51 reads (22%) | catalogued as COSV100954270; called by muse, mutect2, varscan2
